Gene-level copy-number profile of tumor specimen C3L-01836-02 from CPTAC case C3L-01836, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.1 years (17,215 days).
Specimen C3L-01836-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ece8a5e0-a8a4-49c9-b9a6-49fd17cfa904.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01836-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/74baaaf9-80f1-4228-a29d-37eda389bc6c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,615; copy number 1: 3,876; copy number 2: 51,021; copy number 3: 51; copy number 4: 25; copy number 5: 1,327; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 2,612 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–86,496,996, 1,314 genes (broad region; genes not listed).
- chr6:78,604,467–170,738,536, 1,298 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,328 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:107,699,392–108,382,098, 5 genes, copy number 5: AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17.
- chr5:113,022,099–181,342,213, 1,321 genes, copy number 5 (broad region; genes not listed).
- chr16:32,475,051–32,478,250, 1 gene, copy number 9: ABCD1P3.
- chr21:46,690,764–46,691,226, 1 gene, copy number 5: RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 1,033. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
